Somatic mutation profile of tumor specimen C3N-00437-02 (aliquot CPT0012550008) from CPTAC case C3N-00437, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 69.8 years (25,495 days).
Specimen C3N-00437-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d16d8bed-e123-4934-9c9e-1092713cf721.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00437-31 (Blood Derived Normal), aliquot CPT0012620002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b37142c6-d86e-4223-9943-16f41c2f8e71

The open-access MAF lists 104 somatic variants for this specimen: 63 protein-altering or splice-affecting, 21 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 21, Intron 14, Frame Shift Del 7, Nonsense Mutation 2, 5'UTR 2, 5'Flank 2, RNA 1, 3'UTR 1, Translation Start Site 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AARS1 | c.2503G>T p.A835S | Missense Mutation (SNP) | VAF 178/627 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as rs775304067; called by muse, mutect2, varscan2
- ADGRB1 | c.3352G>A p.V1118M | Missense Mutation (SNP) | VAF 38/387 reads (10%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.999); catalogued as rs781741541; called by muse, mutect2, varscan2
- ADH7 | c.1099A>G p.I367V | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.104); catalogued as rs1385786745; called by muse, mutect2, varscan2
- BRINP2 | c.1852G>T p.V618L | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs759731438, COSV64175526; called by muse, mutect2, varscan2
- CCDC9B | c.671C>T p.P224L | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); catalogued as rs749903593; called by muse, mutect2
- CLCA4 | c.1291G>A p.A431T | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.219); catalogued as rs763904592; called by muse, mutect2, varscan2
- CYP7A1 | c.1090C>T p.R364W | Missense Mutation (SNP) | VAF 60/500 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs149291486; called by muse, mutect2, varscan2
- DVL1 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.616); catalogued as rs1375216646, COSV101127283; called by muse, mutect2, varscan2
- FBXO43 | c.1096C>T p.P366S | Missense Mutation (SNP) | VAF 35/352 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV71053744; called by muse, mutect2
- GAL | c.263G>T p.R88L | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.633); catalogued as COSV55763762; called by muse, mutect2, varscan2
- GFOD1 | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.195); catalogued as rs771312460, COSV64954663; called by muse, mutect2, varscan2
- IER3 | c.368C>T p.T123I | Missense Mutation (SNP) | VAF 69/284 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs1014107448, COSV52543581, COSV52544563; called by muse, mutect2, varscan2
- LRRC4B | c.771G>T p.K257N | Missense Mutation (SNP) | VAF 77/296 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.963); catalogued as COSV100975878; called by muse, mutect2, varscan2
- OR6C68 | c.734T>A p.V245E | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1007875087; called by muse, mutect2
- RBMXL3 | c.2825G>A p.R942H | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.84); catalogued as rs868941610, COSV57762046; called by muse, mutect2, varscan2
- TMEM210 | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.711); catalogued as rs772030467; called by muse, mutect2, varscan2
- VHL | c.419del p.L140Pfs*19 | Frame Shift Del (DEL) | VAF 110/401 reads (27%) | catalogued as CD983003, COSV56568261; called by mutect2, pindel, varscan2
- ADAMTS20 | c.5641G>A p.E1881K | Missense Mutation (SNP) | VAF 14/177 reads (8%) | SIFT tolerated (0.77); PolyPhen benign (0.089); called by muse, mutect2
- APOB | c.10781G>T p.W3594L | Missense Mutation (SNP) | VAF 30/193 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- ATE1 | c.1240C>G p.P414A | Missense Mutation (SNP) | VAF 33/224 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, varscan2
- BAP1 | c.338_350del p.S113Tfs*70 | Frame Shift Del (DEL) | VAF 76/320 reads (24%) | called by mutect2, pindel, varscan2
- CACNB1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 19/155 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- CARD6 | c.592C>A p.Q198K | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CASZ1 | c.1056_1065del p.G353Afs*73 | Frame Shift Del (DEL) | VAF 48/223 reads (22%) | called by mutect2, pindel, varscan2
- CDCA3 | c.304T>C p.S102P | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2
- CFAP251 | c.1901A>C p.N634T | Missense Mutation (SNP) | VAF 179/465 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- CPSF1 | c.2248G>C p.D750H | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- CREBL2 | c.179G>T p.R60I | Missense Mutation (SNP) | VAF 16/324 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2
- DNAH5 | c.13714G>C p.E4572Q | Missense Mutation (SNP) | VAF 46/425 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- DSC1 | c.2109_2116+11del p.X703_splice | Splice Site (DEL) | VAF 25/78 reads (32%) | called by mutect2, pindel, varscan2
- EBF3 | c.306G>C p.E102D | Missense Mutation (SNP) | VAF 12/270 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.255); called by muse, mutect2
- FAM170B | c.468G>A p.M156I | Missense Mutation (SNP) | VAF 73/242 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- IGHM | c.64A>C p.S22R | Missense Mutation (SNP) | VAF 100/251 reads (40%) | SIFT tolerated (0.23); called by muse, mutect2, varscan2
- KCNT2 | c.889C>T p.Q297* | Nonsense Mutation (SNP) | VAF 10/202 reads (5%) | called by muse, mutect2
- KLHL10 | c.282dup p.E95* | Frame Shift Ins (INS) | VAF 39/271 reads (14%) | called by mutect2, pindel, varscan2
- KSR2 | c.1948A>G p.S650G | Missense Mutation (SNP) | VAF 36/269 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); called by muse, varscan2
- MBLAC2 | c.517G>T p.G173C | Missense Mutation (SNP) | VAF 94/175 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MFSD9 | c.449C>A p.S150Y | Missense Mutation (SNP) | VAF 42/280 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NOL12 | c.34G>T p.D12Y | Missense Mutation (SNP) | VAF 35/177 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- OPTN | c.1565G>T p.G522V | Missense Mutation (SNP) | VAF 102/408 reads (25%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- OVCH1 | c.449del p.K150Sfs*62 | Frame Shift Del (DEL) | VAF 24/209 reads (11%) | called by mutect2, pindel
- PARP9 | c.108G>C p.Q36H | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- PCDHGC3 | c.328T>A p.L110M | Missense Mutation (SNP) | VAF 205/455 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- PDK2 | c.1064A>T p.D355V | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PHRF1 | c.1956A>C p.R652S (on ENST00000264555 / NM_001286581.2; = p.R651S on NM_020901.4) | Missense Mutation (SNP) | VAF 40/234 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIWIL1 | c.1543C>A p.L515I | Missense Mutation (SNP) | VAF 8/189 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PKDREJ | c.3274G>T p.D1092Y | Missense Mutation (SNP) | VAF 73/281 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PRKACA | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- RCOR3 | c.653del p.P218Lfs*6 | Frame Shift Del (DEL) | VAF 62/323 reads (19%) | called by mutect2, pindel, varscan2
- RHOBTB1 | c.272A>G p.K91R | Missense Mutation (SNP) | VAF 10/175 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.078); called by muse, mutect2
- RNF34 | c.1307T>G p.L436R | Missense Mutation (SNP) | VAF 65/529 reads (12%) | PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RSF1 | c.1229_1235del p.T410Sfs*3 | Frame Shift Del (DEL) | VAF 16/144 reads (11%) | called by mutect2, pindel, varscan2
- SEPSECS | c.580G>T p.E194* | Nonsense Mutation (SNP) | VAF 39/218 reads (18%) | called by muse, mutect2, varscan2
- SETD2 | c.2727T>G p.D909E | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SI | c.228C>G p.N76K | Missense Mutation (SNP) | VAF 54/217 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SLC25A53 | c.595A>T p.I199F | Missense Mutation (SNP) | VAF 37/213 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- SLIT2 | c.4159C>G p.P1387A | Missense Mutation (SNP) | VAF 26/175 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLX4IP | c.319C>G p.L107V | Missense Mutation (SNP) | VAF 10/249 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- THEGL | c.1229del p.T410Ifs*13 | Frame Shift Del (DEL) | VAF 21/155 reads (14%) | called by mutect2, pindel, varscan2
- TNC | c.5613A>T p.K1871N | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- TTC23 | c.84C>A p.F28L | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2
- ZNFX1 | c.3778C>T p.L1260F | Missense Mutation (SNP) | VAF 76/365 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ZXDA | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- AFF2 | c.612C>G p.P204= | Silent (SNP) | VAF 34/299 reads (11%) | catalogued as COSV60678872; called by muse, mutect2, varscan2
- AFF2 | c.948G>T p.G316= | Silent (SNP) | VAF 34/232 reads (15%) | catalogued as rs782587704; called by muse, mutect2, varscan2
- BRCA2 | c.8265A>G p.G2755= | Silent (SNP) | VAF 19/114 reads (17%) | catalogued as rs781363913; ClinVar: likely benign; called by muse, mutect2, varscan2
- C2orf81 | c.1110T>G p.S370= | Silent (SNP) | VAF 14/86 reads (16%) | called by muse, mutect2, varscan2
- CHEK2 | c.90C>A p.G30= | Silent (SNP) | VAF 41/179 reads (23%) | called by muse, mutect2, varscan2
- FAM104A | c.486C>T p.L162= | Silent (SNP) | VAF 120/450 reads (27%) | called by muse, varscan2
- IGFBP3 | c.181C>T p.L61= | Silent (SNP) | VAF 14/62 reads (23%) | called by muse, mutect2, varscan2
- INTS6 | c.351T>G p.P117= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV60881314; called by muse, mutect2
- KSR2 | c.1947C>A p.A649= | Silent (SNP) | VAF 36/261 reads (14%) | catalogued as COSV100195742; called by muse, varscan2
- MAGEL2 | c.3141G>T p.V1047= | Silent (SNP) | VAF 35/206 reads (17%) | called by muse, mutect2, varscan2
- MAPT | c.576C>T p.A192= | Silent (SNP) | VAF 10/162 reads (6%) | called by muse, mutect2
- MAT1A | c.576T>C p.N192= | Silent (SNP) | VAF 50/514 reads (10%) | called by muse, mutect2
- MORC2 | c.2970G>A p.T990= (on ENST00000397641 / NM_001303256.3; = p.T928= on NM_014941.3) | Silent (SNP) | VAF 70/482 reads (15%) | catalogued as rs781327828, COSV53203448; ClinVar: likely benign; called by muse, mutect2, varscan2
- NXPE1 | c.474C>T p.D158= (on ENST00000424269; = p.D16= on NM_152315.5) | Silent (SNP) | VAF 41/157 reads (26%) | called by muse, mutect2, varscan2
- PNPLA7 | c.3810C>T p.D1270= | Silent (SNP) | VAF 31/112 reads (28%) | catalogued as rs138586605; called by muse, mutect2, varscan2
- PXDN | c.69G>A p.G23= | Silent (SNP) | VAF 53/456 reads (12%) | catalogued as rs995355920; called by muse, mutect2, varscan2
- RBM34 | c.135C>T p.G45= | Silent (SNP) | VAF 17/217 reads (8%) | called by muse, mutect2
- RRP7A | c.418C>T p.L140= | Silent (SNP) | VAF 29/211 reads (14%) | called by muse, mutect2, varscan2
- SEMA4G | c.2268C>T p.I756= (on ENST00000370250; = p.I761= on NM_017893.3) | Silent (SNP) | VAF 15/65 reads (23%) | called by muse, mutect2, varscan2
- TFAP2D | c.745T>C p.L249= | Silent (SNP) | VAF 24/122 reads (20%) | catalogued as rs549396552; called by muse, mutect2, varscan2
- TFEC | c.312T>A p.I104= | Silent (SNP) | VAF 36/165 reads (22%) | called by muse, mutect2, varscan2
- AC092329.3 | c.-211-303G>T | Intron (SNP) | VAF 15/79 reads (19%) | called by muse, mutect2, varscan2
- CHST10 | c.-104+394_-104+395del | Intron (DEL) | VAF 69/248 reads (28%) | called by mutect2, pindel, varscan2
- CNOT8 | c.311+2339G>A | Intron (SNP) | VAF 16/50 reads (32%) | called by muse, mutect2, varscan2
- CXCL5 | c.326+44G>C | Intron (SNP) | VAF 37/168 reads (22%) | called by muse, mutect2, varscan2
- FUT7 | chr9:137034775 C>A | 5'Flank (SNP) | VAF 94/247 reads (38%) | catalogued as rs371943249; called by muse, mutect2, varscan2
- HTR3A | c.68-260G>A | Intron (SNP) | VAF 10/75 reads (13%) | catalogued as rs1214385401; called by muse, mutect2, varscan2
- LINC01956 | n.380G>A | RNA (SNP) | VAF 80/255 reads (31%) | catalogued as rs925586377; called by muse, mutect2, varscan2
- LY6E | chr8:143018218 C>T | 5'Flank (SNP) | VAF 264/464 reads (57%) | called by muse, mutect2, varscan2
- MDM4 | c.412-289A>C | Intron (SNP) | VAF 32/135 reads (24%) | called by muse, mutect2, varscan2
- NDUFV2 | c.54+1404G>T | Intron (SNP) | VAF 26/148 reads (18%) | called by muse, varscan2
- NFX1 | c.*14C>T | 3'UTR (SNP) | VAF 48/127 reads (38%) | called by muse, mutect2, varscan2
- NKRF | c.-17+2256C>A | Intron (SNP) | VAF 25/188 reads (13%) | called by muse, mutect2, varscan2
- NPHP3 | c.393+194C>G | Intron (SNP) | VAF 10/93 reads (11%) | called by muse, mutect2, varscan2
- POLR2B | c.-18C>T | 5'UTR (SNP) | VAF 53/209 reads (25%) | called by muse, mutect2, varscan2
- PRDX2 | c.257+53C>A | Intron (SNP) | VAF 19/236 reads (8%) | called by muse, mutect2
- SAMD13 | c.226-4374A>G | Intron (SNP) | VAF 20/84 reads (24%) | called by muse, mutect2
- SLC16A2 | c.-1G>A | 5'UTR (SNP) | VAF 34/474 reads (7%) | called by muse, mutect2
- ST20-MTHFS | c.-12+473G>A | Intron (SNP) | VAF 17/83 reads (20%) | called by muse, mutect2, varscan2
- TGM2 | c.859+109C>T | Intron (SNP) | VAF 29/166 reads (17%) | called by muse, mutect2, varscan2
- TMEM191B | c.796-35_796-24del | Intron (DEL) | VAF 6/58 reads (10%) | called by mutect2, pindel
